Gene-level copy-number profile of tumor specimen TCGA-58-A46N-01A from TCGA case TCGA-58-A46N, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Basaloid squamous cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 52.2 years (19,050 days).
Specimen TCGA-58-A46N-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.3ef3370f-117e-435f-b769-364a17369726.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-58-A46N-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/14e074ca-5459-4fd9-8d2c-dbcc2ee8f1ff

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 35; copy number 1: 106; copy number 2: 33,035; copy number 3: 3,002; copy number 4: 21,294; copy number 5: 311; copy number 6: 128; copy number 7: 1,064; copy number 8: 53; copy number 9: 688; copy number 10: 54; copy number 12: 33; copy number 18: 11; copy number 26: 3.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-58-A46N-01A-11D-A24C-01): tumor purity 0.89, ploidy 1.49, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 35 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,601,506–181,100,666, 24 genes (within-gene range 0–2): FLT4, AC122714.2, LINC02222, OR2AI1P, RNU1-17P, OR2Y1, MGAT1, AC022413.1, HEIH, LINC00847, AC022413.2, ZFP62, BTNL8, Y_RNA, RPS29P12, AC091874.2, AC091874.1, ARPP19P1, BTNL3, RNU6-1036P, BTNL9, MIR8089, AC008620.1, FOXO1B.
- chr11:134,563,396–135,075,908, 11 genes: AP004550.1, AP001999.3, AP001999.1, AP001999.2, LINC02706, LINC02714, AP003062.2, LINC02697, AP003062.1, LINC02717, LINC02684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,345 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,434,166–121,580,524, 63 genes, copy number 6–8 (broad region; genes not listed).
- chr1:188,869,474–189,993,097, 9 genes, copy number 6: AL691515.2, LINC01035, CLPTM1LP1, GAPDHP75, RNA5SP73, LINC01701, AL591504.1, AL591504.2, AL359976.1.
- chr3:93,843,764–198,222,513, 1,800 genes, copy number 6–9 (broad region; genes not listed).
- chr5:2,921,496–3,536,094, 5 genes, copy number 6: AC094105.2, LINC01377, LINC01019, LINC02162, LINC01017.
- chr6:17,582,034–27,965,514, 256 genes, copy number 5 (broad region; genes not listed).
- chr6:54,485,169–66,094,909, 88 genes, copy number 5–26 (broad region; genes not listed).
- chr7:87,503,017–87,713,323, 1 gene, copy number 6 (within-gene range 4–6): ABCB1.
- chr7:87,627,548–88,756,725, 16 genes, copy number 6 (within-gene range 4–6): RUNDC3B, SLC25A40, DBF4, ADAM22, SRI, SRI-AS1, AC003991.1, STEAP4, AC002069.2, EIF4A1P13, AC002069.1, AC002069.4, AC002069.3, KPNA2P2, PQLC1P1, EEF1A1P28.
- chr14:35,401,513–35,809,304, 7 genes, copy number 6 (within-gene range 4–6): NFKBIA, DNAJC8P1, AL133163.3, RPS3AP4, KRT18P6, INSM2, RALGAPA1.
- chr14:84,172,841–85,654,428, 13 genes, copy number 5: MTND4P33, MTND5P35, MTCYBP27, RNU6-976P, AL163642.1, AL163642.2, AL357172.1, AL049775.2, LINC02329, LINC00911, AL049775.1, AL049775.3, FLRT2.
- chr18:580,380–4,459,458, 87 genes, copy number 10–12 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 106. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
